Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-AE8U, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-AE8U-TTM1-A (Metastatic).

[page 1 of 12]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR: [REDACTED]
PAT TYPE: 0

PAGE #: 1
SEX: M
ADM DATE: [REDACTED] +0

ACCESSION:

OPER DATE: [REDACTED] +0

REQ DOC:

PROCEDURE: SPHS

VERIFIED BY:

Source of specimen: Tru-cut bx L scapula mass. History of case: Status post fall x2. mass seen approximately 5 months ago, slowing growing. Clinical Diagnosis: L shoulder mass. Operative Procedure/Tissue Submitted: Tru-cut bx L scapula.

PROCEDURE: SPGD

VERIFIED BY:

1. "Tru-cut bx L scapula mass". A 1.3 x 1.3 x 0.3 cm aggregate of tan bits.
- 1A. Frozen section control.

FROZEN SECTION REPORT

1. Positive for metastatic renal cell carcinoma.

I, [REDACTED] have reviewed and interpreted the frozen section material at the time it was requested.

Permanent section confirms frozen section report.

PROCEDURE: SPDX

VERIFIED BY:

1. Left scapula, biopsy: Metastatic clear cell renal cell carcinoma.

I, [REDACTED] the signing staff pathologist, have personally examined and interpreted the slides from this case.

** END OF PREVIOUS DIAGNOSIS INQUIRY **

[page 2 of 12]
Results

CT ABDOMEN PELVIS W IV CONTRAST

(Accession)

Narrative

EXAMINATION: CT scan of the abdomen and pelvis following oral and IV contrast

COMPARISON STUDY: None.

HISTORY: Evaluate for lymphadenopathy or mass.

TECHNIQUE: CT scan of the abdomen and pelvis following oral and IV contrast. DFOV 36 cm. Oral contrast given. 125 mL of Isovue 300 were injected intravenously without complication.

FINDINGS:

Please see chest CT report for thoracic findings.

ABDOMEN:

Liver is homogeneous in attenuation with suggestion of a subcentimeter hypervascular lesion, in the left lobe lateral segment (series 3, image 49). Spleen is normal. Gallbladder is contracted, but unremarkable. No biliary ductal dilation.

Pancreas is atrophic. Near the uncinate process on the undersurface of the pancreas there are two low-attenuation septated lesion measuring approximately 2.0 x 1.4 cm on series 3, image 499. There is another lobulated low attenuation lesion at the tail of the pancreas measuring approximately 2.3 x 1.7 cm. A third low-attenuation lesion is seen in the body of the pancreas measuring approximately 7 mm.

There is a heterogeneously enhancing mass arising from the right kidney upper/intra polar region measuring approximately 7.6 x 7.4 x 7.0 cm (CC, transverse, and AP). Mass abuts the right hepatic lobe with no definite fat plane intervening making it difficult to exclude local extension into the right hepatic lobe. A subcentimeter low-attenuation lesion is seen within the lower pole of the right kidney (series 3, image 499). There is neovascularity within the retroperitoneum. The right adrenal gland appears to be normal. No definite tumor thrombus is seen in the right renal vein or IVC.

A questionable lesion within the left kidney upper pole (series 3, image 491). Nodular thickening, which is enhancing, is noted in the left adrenal gland suspicious for metastatic disease.

PELVIS :

No free fluid. Artifact from hip arthroplasty does limit evaluation of the pelvis.

There is diffuse muscular atrophy involving the left psoas and paraspinal musculature as well as the left thigh musculature.

IMPRESSION:

1. Large approximately 7.6 x 7.4 x 7.0 cm heterogeneously enhancing right renal mass, most likely representing primary renal cell carcinoma. No evidence of renal vein or IVC thrombus. Adjacent local right hepatic lobe invasion is difficult to exclude.
2. Nodular thickening of the left adrenal gland suspicious for metastatic disease.
3. Multiple lobulated low attenuation lesions of the pancreas which

Baseline

[page 3 of 12]
likely represent sidebranch IPMN's. Attention on follow-up is suggested.

4. Possible left upper pole renal lesion as described above. Attention on follow-up is suggested.

5. Possible subcentimeter hypervascular left hepatic lobe lesion as described above. Attention on follow-up is suggested.

6. Diffuse muscular atrophy involving the left paraspinal and thigh musculature.

Please see chest CT report for thoracic findings.

UNEXPECTED TEST RESULT COMMUNICATION:

The unexpected test result, large right renal mass with possible hepatic invasion, questionable small hepatic metastases, and contralateral adrenal metastasis was discussed with [REDACTED] on [REDACTED].

Result I

Exam Date	Time	Prelim Radiologist	Pager#	Prelim Date	Reading Radiologist	Pager#	Read Date
--------------	------	-----------------------	--------	-------------	------------------------	--------	-----------

[page 4 of 12]
Results

CT THORAX W IV CONTRAST

Narrative

PROCEDURE: CT CHEST WITH CONTRAST - CHEST PROTOCOL

CLINICAL INDICATION: lymphadenopathy, mass .

COMPARISON: None.

TECHNIQUE: Helical CT was performed of the chest (lung apices to bases) using 125 mL Isovue-300 nonionic intravenous contrast, without complication. Images were reconstructed at 2.5 mm and 1.25 mm slice thickness. (DFOV = 36 cm)

FINDINGS:

Lungs: Innumerable bilateral pulmonary nodules and masses ranging in size from the 0.2 to 3 cm are concerning for metastatic disease. The largest nodule is along the right major fissure measuring 3 x 2.7 cm.

Central Airway: A soft tissue nodule in the lingular lobe bronchus on image #224 series 3 likely represents endobronchial metastasis. Another endobronchial lesion is present in left upper lobe apicoposterior segmental bronchus on image #169 series 3.

Pleura: No pleural effusion, thickening or pneumothorax.

Thoracic aorta and great vessels: Normal in diameter.

Pulmonary arteries: Unremarkable.

Heart and pericardium: Moderate coronary arterial calcification. Unremarkable cardiac morphology and pericardium.

Lymph nodes: No enlarged thoracic lymph nodes.

Lower neck/mediastinum: Unremarkable.

Thoracic spine and chest wall: There is a large lobulated enhancing mass with central necrosis centered around the left scapula. The mass is only partially visualized and measures approximately 11 x 12 cm. It is destroying the left scapula blade. Prominent collateral vessels are present around the mass in the left shoulder region. There is atrophy of the left paraspinal muscles. There is wedge compression deformity of the midthoracic vertebral bodies.

Visualized upper abdomen: Please see a separate dictation for CT of the abdomen and pelvis.

IMPRESSION:

1. Partially visualized heterogenous enhancing mass with central necrosis in left shoulder region, destroying the left scapular blade. This could represent either a primary sarcoma of the chest wall or the metastatic lesion arising from the right renal mass.

2. Innumerable bilateral pulmonary metastases. Endobronchial metastases in the left upper lobe.

Baseline

Result

Exam Date	Exam Time	Prelim Radiologist	Read Date	Prelim Date	Reading Radiologist	Pager#	Read Date
-----------	-----------	--------------------	-----------	-------------	---------------------	--------	-----------

[page 5 of 12]
Results

CT THORAX W IV CONTRAST

Narrative

PROCEDURE: CHEST WITH CONTRAST - CHEST PROTOCOL

CLINICAL INDICATION: Surveillance for RCC

COMPARISON: [REDACTED] -6 [REDACTED]

TECHNIQUE: Helical CT was performed of the chest (lung apices to bases) using 125 mL Isovue-300 nonionic intravenous contrast, without complication. Images were reconstructed at 1.25 mm slice thickness. MIP and coronal & sagittal MPR images were generated and reviewed. (DFOV = 36 cm)

Best response

FINDINGS:

Lower neck/thyroid: Unremarkable.

Lungs: Interval slight decrease in size in numerous bilateral pulmonary nodules and masses. For example:
Right lower lobe nodule image 370 of series 3 measures 15 x 12 mm and previously measured 20 x 15 mm,
Left lower lobe nodule image 348 measures 15 x 16 mm and previously measured 22 x 18 mm,
Right upper lobe nodule image 154 measures 18 x 16 mm and previously measured 21 x 16 mm,
Left upper lobe nodule image 293 measures 10 mm and previously measured 12 mm.

Central airway: Unremarkable.

Pleura: No pleural effusion.

Thoracic aorta and great vessels: Atherosclerotic changes of thoracic aorta. Thoracic aorta is normal in caliber. Normal aortic arch branching pattern.

Pulmonary arteries: No central pulmonary embolism. Most likely an artifact in the subsegmental left lower lobe pulmonary artery image 294.

Heart and pericardium: Extensive coronary arterial calcification. Unremarkable cardiac morphology and pericardium.

Lymph nodes: 25 x 31 mm left hilar lymph node image 235 of series 3, stable. Right hilar lymph node image 253 measuring 25 mm, stable.

Mediastinum: Small hiatal hernia.

Thoracic spine and chest wall: Incompletely included within the field-of-view large centrally necrotic and heterogeneously enhanced lesion around and involving the left scapula. Redemonstration of mild wedge compression deformity involving midthoracic spine. Osteopenia. Atrophy of the paraspinal muscles.

Other Lines/Tubes/Devices/Hardware: None

Visualized upper abdomen: Large visualized enhancing mass arising from the upper pole of the right kidney. Please refer to separate CT abdomen and pelvis report.

IMPRESSION:

1. Interval slight decrease in size in numerous bilateral pulmonary nodules as detailed above.

[page 6 of 12]
2. No other interval changes.

Result Information

Exam Date	Exam Time	Prelim Radiologist	Pager#	Prelim Date	Reading Radiologist	Pager#	Read Date
--------------	--------------	-----------------------	--------	-------------	------------------------	--------	-----------

+91

+91

+91

Best response

[page 7 of 12]
Results

CT ABDOMEN PELVIS W IV CONTRAST

Narrative

CT scan of [REDACTED] and pelvis dated [REDACTED]

Indication: Metastatic renal cell carcinoma.

Technique: 5 mm axial sections of abdomen and pelvis have been obtained following uneventful administration of oral contrast and 125 cc Isovue-300 as intravenous contrast. DFOV is 36 cm.

Comparison: [REDACTED] -6 [REDACTED]

Findings:

Abdomen:

No focal lesions are noted in liver suspicious for metastasis. The previously suggested possible hypervascular lesion in left lobe of liver is not appreciated on the current CT examination. Gallbladder, spleen, are unremarkable. Stable lobulated cystic lesion with septations arising from uncinate process of pancreas measuring approximately 4 x 1.8 cm and a 1 cm lesion in proximal body of pancreas (image 569 series 3) likely representing sidebranch intraductal papillary mucinous neoplasms (IPMN). No dilation of main pancreatic duct is seen.

1st response

Large heterogeneous mass in upper pole of right kidney relatively stable in size measuring approximately 8 x 8 cm in transverse dimension and 7.5 cm in craniocaudal dimension. There is possible extension into branches of right renal vein (image 569 series 3). The right main renal vein is patent. IVC is patent.

A 2 mm nonobstructing calculus in lower pole of left kidney is unchanged. Few tiny subcentimeter hypodense lesions are noted in left kidney likely representing cysts. No solid enhancing left renal mass is seen.

Stable 1 cm nodule in left adrenal gland. Right adrenal gland is unremarkable.

No enlarged lymph nodes are noted in abdomen. Bowel loops are normal in caliber. No free fluid is seen.

Pelvis:

Urinary bladder is unremarkable. Evaluation of pelvic structures is limited by beam hardening artifacts from right hip prosthesis.

There is redemonstrated fatty replacement of muscles around the left hip joint and proximal thigh.

No aggressive lesions are noted in visualized bones.

Impressions:

1. Stable 8 cm heterogeneously enhancing right renal mass. No thrombosis of right renal vein or IVC seen.
2. Stable 1 cm left adrenal nodule.
3. No evidence of hepatic metastases or metastatic lymphadenopathy in abdomen and pelvis.
4. Stable cystic lesions in pancreas likely representing sidebranch IPMNs.

[page 8 of 12]
5. Tiny nonobstructing left calculus.

A chest CT was obtained, to be reported separately.

Best response

Result Information

Exam Date	Exam Time	Prelim Radiologist	Pager#	Prelim Date	Reading Radiologist	Pager#	Read Date
[REDACTED]				[REDACTED]			[REDACTED]
+91				+91			+91
					[REDACTED]		
					[REDACTED]		
					[REDACTED]		

[page 9 of 12]
Results

CT THORAX W IV CONTRAST

Narrative

PROCEDURE: CHEST WITH CONTRAST - CHEST PROTOCOL

CLINICAL INDICATION: re-staging of renal cell cancer

COMPARISON: [REDACTED] +370

Progression

TECHNIQUE: Helical CT was performed of the chest (lung apices to bases) using 125 mL Isovue-300 nonionic intravenous contrast, without complication. Images were reconstructed at 1.25 mm slice thickness. MIP and coronal & sagittal MPR images were generated and reviewed. (DFOV = 36 cm)

FINDINGS:

Lower neck/thyroid: Redemonstration of extensive expansile lytic lesion with prominent soft tissue component overlying the left scapula with heterogeneous enhancement and areas of low attenuations which most likely represents areas of necrosis. The lesion extends into the base of the neck, incompletely included within the field-of-view and distally does distal to the scapula.

Lungs: Interval slight decrease in size in numerous bilateral pulmonary nodules/masses. For example 26 mm right upper lobe mass image 191 of series 3 measured 29 mm, right peri hilar mass image 246 measures 31 mm, previously measured 38 mm, Right lower lobe nodule crossing the major fissure (or intrapulmonary lymph node) image 222 of series 3 measures 21 mm, previously measured 25 mm, left lower lobe nodule measuring 17 mm image 285, previously measured 20 millimeters.

Central airway: Unremarkable.

Pleura: Stable small to moderate layering left pleural effusion with adjacent atelectasis. The enhancing left pleural based nodules are stable. For example image #342 of series 3 the pleural based nodule measures 30 x 21 mm.

Thoracic aorta and great vessels: Normal in diameter.

Pulmonary arteries: Unremarkable.

Heart and pericardium: Moderate coronary arterial calcification. Mitral valve annulus calcification. Aortic valve calcification.

Lymph nodes: 29 x 36 mm left suprahilar lymph node image 201 of series 3, previously measured 34 x 33 mm.

Mediastinum: Unremarkable.

Thoracic spine and chest wall: Osteopenia with degenerative changes of thoracic spine. Degenerative changes of the right shoulder. Mild wedging of meet thoracic vertebral body.

Other Lines/Tubes/Devices/Hardware: None

Visualized upper abdomen: Right renal mass. Please refer to separate CT abdomen/pelvis report.

IMPRESSION:

1. Interval slight decrease in size in numerous bilateral pulmonary nodules as detailed above.

[page 10 of 12]
2. No other interval changes.

Result Information

Exam Date	Exam Time	Prelim Radiologist	Pager#	Prelim Date	Reading Radiologist	Pager#	Read Date
[REDACTED]				[REDACTED]			[REDACTED]
+426				+426			+426

progression

[page 11 of 12]
Results

CT ABDOMEN PELVIS W IV CONTRAST

Narrative

CT abdomen pelvis with contrast

Clinical history: Renal cell cancer, restaging

Technique: Axial CT images of the abdomen and pelvis were obtained with oral and intravenous contrast (125ml of Isovue-300). DFOV 36.0 cm.

Comparison: [REDACTED] +271

Findings:

Abdomen:

Dedicated CT images of the chest were also obtained and will be reported separately.

There is a large heterogeneous mass within the right kidney, measuring 6.4 x 7.0 cm in greatest axial dimension (image 538 series 3). There are large areas of central necrosis and high attenuation components which may represent dystrophic calcination and/or treatment effect. Some areas of residual soft tissue enhancement are noted about the periphery the lesion. Teslas of features is compatible with renal cell carcinoma, and is similar in size to comparison study of [REDACTED] with +365 overall decrease in size versus more remote comparison study of [REDACTED] +271. There are a few tiny subcentimeter low-attenuation foci within the lower pole of right kidney, too small to definitively characterize, perhaps small cysts.

There is a stable subcentimeter low-attenuation focus in the medial segment left hepatic lobe (545 series 3), which could represent a cyst given its presence on multiple prior studies. There is a peripheral enhancing lesion in the lateral segment left hepatic lobe measure 1.1 x 1.6 cm, which is difficult to appreciate on the comparison study due to noncontrast technique, but is not clearly evident on the more remote comparison contrast enhanced studies. There is also a new subcentimeter low-attenuation focus near the junction of the right and left hepatic lobes (image 539 series 3), which could represent a small developing metastasis given the temporal evolution. Continued attention to this area on follow-up is suggested.

The spleen, gallbladder, and biliary tree are unremarkable. Previously seen left adrenal nodule has decreased in size/conspicuity, currently measuring up to 1.4 cm, previously 1.8 cm from [REDACTED] study. There are multiple low-attenuation foci in the pancreatic head and uncinate region, which have increased in size versus comparison study of [REDACTED] +271. As an example, a dominant focus measures up to 3.8 cm on image 549 series 3, previously 2.9 cm. There are additional cystic foci in the pancreatic tail region which are grossly unchanged. Differential considerations again include pseudocyst, sidebranch IPMN, or treated metastasis.

There is a small nonobstructing calculus in lower pole left kidney, unchanged. The bowel is grossly nonobstructive. No substantial free fluid.

Pelvis:

Evaluation is somewhat limited given streak artifact from indwelling hip arthroplasty device. Urinary bladder is grossly unremarkable. No enlarged lymph nodes. No substantial free fluid.

Major vascular structures are patent. There is atherosclerotic vascular calcification. Extensive muscular atrophy is noted within the left hip and thigh. There is a 1.4 x 1.9 cm enhancing focus adjacent to the right hip arthroplasty device (image 586 series 3), which has increased

Progression

[page 12 of 12]
+271

in size from comparison study of [REDACTED] and probably represents a soft tissue metastasis. There are degenerative in the spine. No destructive osseous lesion.

IMPRESSION:

+365

1. Large heterogeneous mass in right kidney, similar in configuration to comparison study of [REDACTED] but decreased versus more remote comparison study of [REDACTED]. This likely represents reported history renal cell carcinoma, noting posttreatment changes as above.

+271

Progression

2. Peripherally enhancing mass in lateral segment left hepatic lobe, new from comparison contrast enhanced study of [REDACTED], likely +271 metastasis. This is difficult to appreciate on [REDACTED] comparison study given noncontrast technique. There is an additional subcentimeter low-attenuation focus in the junction of right and left hepatic lobes, possibly a small developing metastasis given temporal evolution. Continued attention to this on follow-up is warranted.

+365

3. Enhancing soft tissue nodule adjacent to right hip arthroplasty device, larger than comparison study of [REDACTED]. This probably +271 represents a soft tissue metastasis.

+365

4. Numerous low-attenuation foci throughout the pancreas, similar to comparison study of [REDACTED], but larger than [REDACTED] study. Primary +271 differential considerations include pancreatic pseudocyst, sidebranch IPMN, or treated metastases.

5. Left adrenal nodule, decreased in size/consistency from both comparison studies

Result

Exam Date	Time	Prelim Radiologist	Pager#	Prelim Date	Reading Radiologist	Pager#	Read Date
-----------	------	--------------------	--------	-------------	---------------------	--------	-----------

Source: NCI Genomic Data Commons file 7513772b-6055-48f6-96d5-e988b91971a9 (ER0062 ER-AE8U Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).